Clinical report (de-identified scan), EXCEPTIONAL_RESPONDERS case ER-ABXQ, project EXCEPTIONAL_RESPONDERS-ER (Exceptional Responders), specimen ER-ABXQ-TTP1-A (Primary Tumor).

[page 1 of 7]
Results History

SURGICAL PATHOLOGY (Order [REDACTED])

Result Date - [REDACTED] +8

Component Results

Component

Report, pathology

Provider: [REDACTED]

Collected: [REDACTED]

Case #: [REDACTED]

+0

Surgical Pathology Report

FINAL PATHOLOGIC DIAGNOSIS

A. LEFT CHEEK

- MERKEL CELL CARCINOMA

-NARROWLY TRANSECTED AT DEEP MARGIN

Comment: The following Immunohistochemistries with the appropriate positive and negative controls are performed to document this lesion as a Merkel cell tumor: CK 7, negative. CK 20, focal paranuclear dot positivity. NSE, positive. Synaptophysin, positive. TTF-1, negative. HMB-45, negative. These studies all support a diagnosis of a primary Merkel cell carcinoma. [REDACTED] notified of this diagnosis by phone on [REDACTED] +8

[DISCLAIMER: This immunoperoxidase stain/panel was developed and its performance characteristics determined by the [REDACTED] Laboratory/[REDACTED]. It has not been cleared or approved by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. This test is used for clinical purposes. It should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA-88) as qualified to perform high complexity clinical laboratory testing.]

Clinical History

DIAGNOSIS / CLINICAL IMPRESSION:

1 cheek, 1 cm pink papule

Excision cyst vs basal cell carcinoma vs melanoma vs neoplasm

Gross Description

Received in formalin labeled with the patient's name "[REDACTED]" without designation consists of an ellipse of tan skin measuring 1.8 x 1.5 cm, excised to a depth of 0.5 cm. There is gray white tumor measuring 1 cm in greatest dimension. The margins are inked black. Tip in A1. The remaining tissue in A2

+2

Specimen(s) Received

A: SKIN EXCISION, NOT ORIENTED - left cheek

Patient Name: [REDACTED]

Med. Rec #: [REDACTED]

DOB/Age: [REDACTED]

(Age: [REDACTED])

Sex: M

Facility: [REDACTED]

Location: [REDACTED]

[page 2 of 7]
Result Date - [REDACTED] +2

[page 3 of 7]
Transcription Result

Type	ID	Date and Time	Author
Procedures	[REDACTED]	[REDACTED]	[REDACTED]

Procedure Orders:

1. PET W CONCURRENT CT TUMOR LOCALIZATION, SKULL BASE TO MID THIGH [REDACTED] ordered by [REDACTED]

Document Text +17
PET/CT SCAN

** HISTORY **:

67-year-old male with a large Merkel cell carcinoma of the left cheek.

** FINDINGS **:

Isotope:
19.4 mCi of FDG, IV.

Procedure:

The patient's blood glucose level was 117. The patient was in the supine position for 30 minutes after administration of radiopharmaceutical.

A non-contrast CT scan, used as a transmission scan for attenuation correction and anatomic map for the PET scan, from the top of the skull through the pelvis was acquired followed immediately with an emission PET scan of the same area.

The data was reconstructed in transaxial, coronal, and sagittal views and displayed as PET non-attenuation corrected, PET attenuation corrected, and PET/CT coregistered images. The CT scan obtained was a low energy acquisition and a non-diagnostic quality study used for the purposes of anatomic mapping and attenuation correction of the PET scan.

Findings:

Small, indistinct uptake in the hila (maximal SUV 3.5) is most likely within physiologic limits. No lesions are identified in the head and neck or elsewhere to indicate malignancy as clinically questioned. Scattered, linear uptake of radiopharmaceutical in the abdomen and pelvis is representative of physiologic gastrointestinal and genitourinary tract activity. Bladder morphology is suggestive of an enlarged prostate.

** IMPRESSION **:

Negative PET/CT scan.

[REDACTED]
DD: [REDACTED] DT: [REDACTED]
+17 +17

[REDACTED]

[page 4 of 7]
Transcription Result

Type	ID	Date	Author
Procedures		+1112	

Procedure Orders:

1. CT THORAX, W CONTRAST [REDACTED] ordered by at [REDACTED] +1112
2. CT ABDOMEN AND PELVIS, W CONTRAST [REDACTED] ordered by at [REDACTED] +1112

Document Text

CT CHEST, ABDOMEN & PELVIS W CONTRAST

** HISTORY **:

70Y Male is on chemotherapy. Please compare liver lesion.
Pertinent additional history: Merkel cell carcinoma with left acetabular mass.

** FINDINGS **:

TECHNIQUE: Axial images obtained through the chest, abdomen & pelvis with intravenous and oral contrast per region protocol.
Coronal reformats.

COMPARISON: [REDACTED] +1031

CHEST: Faint groundglass opacity within the left apex is stable. Again noted are several small pulmonary nodules. The largest one measures 5 mm and appears calcified and may be a calcified granuloma. All the other nodules are approximately 2-3 mm and too small to determine if they are calcified or not. No new pulmonary nodule is identified.

Small nonenlarged nodes within the mediastinum, axilla, hila and along the esophagus are stable non-median pathologic criteria for enlargement. No pleural or paracardial effusion. Thoracic aorta is normal caliber.

ABDOMEN/PELVIS: There is been dramatic improvement of the hepatic lesion. Size has reduced to 4.2 x 2.1 cm (previously 10 x 4.2 cm at same measurement location). A small part of the mass extended posterior to the porta hepatis abutting the middle vein and this portion is much smaller measuring 8 mm (previously approximately 2.9 cm). More focal and more well-defined margin hypodensity in along the left hepatic lobe measuring 8mm is stable. No new hepatic lesion is identified. Biliary ducts are not stented. Gallbladder and pancreas appear unremarkable.

Partial atrophic appearance of the right kidney is unchanged. There are bilateral extrarenal pelvis right. Spleen and adrenal glands are unremarkable. Small scattered nodes along the retroperitoneum are stable and do not meet pathologic criteria for enlargement. There is colonic diverticulosis primarily along the distal half. There is again prostatomegaly, a nondistended bladder with mild circumferential wall thickening and a right inguinal region hernia containing mostly fat and a small amount of small bowel without CT signs of incarcerated hernia.

The left iliac bone/acetabular 3.7 x 5.9 cm lytic mass smaller previously measuring 4.4 x 6.3 cm at similar measurement location. No new osteolytic or osteoblastic lesion is appreciable. Scattered degenerative changes are noted.

** IMPRESSION **:

[page 5 of 7]
Significant improvement of the hepatic lesion which is dramatically smaller in size. No new hepatic lesion or pathologic adenopathy. Scattered small lymph nodes appear stable.

Smaller left iliac bone/acetabular lytic mass.

Multiple pulmonary nodules that are subcentimeter in size remain stable. The largest one is calcified likely calcified granuloma. Although metastatic disease cannot be entirely excluded, they could be sequela of old granulomatous disease. They remain indeterminate but stable.

Prostatomegaly, atrophic right kidney, and diverticulosis, right inguinal region hernia.

DD: [REDACTED] DT: [REDACTED]

+1112

[page 6 of 7]
Transcription Result

Type	ID	Date	Author
Procedures	[REDACTED]	[REDACTED] +2122	[REDACTED]

Procedure Orders

- 1 CT THORAX, W CONTRAST [REDACTED] ordered by at [REDACTED] +2122
- 2 CT ABDOMEN AND PELVIS, W CONTRAST [REDACTED] ordered by at [REDACTED] +2122

Document Text

CT CHEST ABDOMEN AND PELVIS

+2122

** HISTORY **:

Followup metastatic Merkel cell cancer

** FINDINGS **:

CT of the chest abdomen and pelvis obtained after the ministration of 100 cc of Omnipaque IV contrast.

CTDI: 21.45 mGy

DLP: 1411.54 mGy-cm

Multiple stable tiny subcentimeter calcified and noncalcified bilateral pulmonary nodules. There are shotty small but numerous thoracic nodes, largest for area measuring 7 mm in the prevascular region and 9 mm in the azygoesophageal recess/paraspinous posterior mediastinum.. No There is nonspecific fatty atrophy of the right shoulder girdle muscles. The patient was unable to raise his right arm.

Artifact from the patient's right arm degrades imaging through the liver. No visible significant change in poorly defined difficult to measure low density lesion in right lobe near gallbladder fossa, residual disease activity uncertain. I cannot exclude a subtle tiny subcapsular low-density lesion in anterior segment of right lobe of liver, not clearly seen on previous examination. Previously noted tiny low-density lesion in left lobe is too small to characterize but stable.

The spleen is small and homogeneous. Shotty portal and abdominal and pelvic nodes are stable, largest for station in the left iliac chain measuring upwards of 11 mm in short axis. Partially visualized left inguinal nodes measure upwards of 1.3 cm in short axis.

No gross change large mixed sclerotic and lytic left iliac bony lesion. Other likely chronic/degenerative sclerotic changes elsewhere are as before.

Severe right renal atrophy and milder left renal scarring and patulous ureters are as before. Heterogeneous enlarged prostate gland a partially decompressed bladder. Bowel containing right inguinal hernia. Multifocal ventral hernias containing

[REDACTED]

[page 7 of 7]
infiltrated fat. Diverticulosis. Aortic atherosclerosis. Gastric diverticulum. Gallbladder is decompressed with crossing artifact and poorly evaluated.

**** IMPRESSION **:**

Stable examination. No significant change poorly defined difficult to measure liver lesion, residual disease activity uncertain. No gross change large mixed sclerotic and lytic lesion of left hemipelvis. Stable shotty borderline prominent nodes across the chest abdomen and pelvis. No change tiny calcified and noncalcified pulmonary nodules in keeping with old granulomatous disease.

Aortic atherosclerosis.

DD:

DT:

+2122

Source: NCI Genomic Data Commons file f026c70a-fe38-4870-988d-24f4c59d58f9 (ER0150 ER-ABXQ Clinical Report_Redacted_Sanitized.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).